Gene-level copy-number profile of specimen HCM-CSHL-0245-C18-85M from HCMI case HCM-CSHL-0245-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVC; Tumor grade: GB; Age at diagnosis: 72.9 years (26,617 days).
Specimen HCM-CSHL-0245-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 66ad2f26-5474-4af0-92eb-fc97234cea70.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0245-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/5090e9ef-5ace-4d27-8374-c4743aceca0c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 1,217; copy number 3: 1,434; copy number 4: 35,587; copy number 5: 8,235; copy number 6: 11,557; copy number 7: 232; copy number 8: 79; copy number 9: 29; copy number 10: 10; copy number 11: 1; copy number 16: 2; copy number 17: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 47 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:49,903,845–49,930,173, 2 genes, copy number 9 (within-gene range 6–9): AC105935.1, MON1A.
- chr6:89,829,894–89,921,760, 6 genes, copy number 10: CASP8AP2, Y_RNA, RPL22P14, AL353692.1, GJA10, Y_RNA.
- chr6:106,695,535–106,788,148, 4 genes, copy number 10: LINC02526, LINC02532, RNU6-117P, MIR587.
- chr7:76,461,676–76,627,982, 10 genes, copy number 9: DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1, POMZP3.
- chr8:7,705,182–7,741,396, 5 genes, copy number 17: OR7E154P, FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P.
- chr8:39,451,045–39,522,852, 1 gene, copy number 11: ADAM3A.
- chr9:41,890,314–42,569,353, 16 genes, copy number 9–16: CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1.
- chr9:107,963,703–108,097,851, 3 genes, copy number 9: RPS15AP27, AC068050.1, CHCHD4P2.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
